Somatic mutation profile of tumor specimen TCGA-HU-8604-01A (aliquot TCGA-HU-8604-01A-11D-2394-08) from TCGA case TCGA-HU-8604, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 82.6 years (30,178 days).
Specimen TCGA-HU-8604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efb7fb8f-e131-454e-bcb4-d837ea87f73c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8604-10A (Blood Derived Normal), aliquot TCGA-HU-8604-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98cbf550-9b78-4805-944b-a29a47e1caba

The open-access MAF lists 230 somatic variants for this specimen: 170 protein-altering or splice-affecting, 56 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 56, Nonsense Mutation 5, Splice Region 4, Frame Shift Del 3, Intron 2, Frame Shift Ins 2, RNA 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXG1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796052469, COSV57397176; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2277G>A p.S759= | Splice Region (SNP) | VAF 14/107 reads (13%) | catalogued as rs765558703, COSV52202939; called by muse, mutect2, varscan2
- ABTB2 | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100131689; called by muse, mutect2, varscan2
- AC092143.1 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs886042295, COSV59247953; called by muse, mutect2, varscan2
- ACSS3 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV54092598; called by muse, mutect2, varscan2
- ADGRE1 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51676334; called by muse, mutect2
- AL592490.1 | c.2572A>G p.R858G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV69424860, COSV69426585; called by muse, mutect2, varscan2
- AMY2B | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.209); catalogued as rs1318616446, COSV63715527, COSV63717225; called by muse, mutect2
- ANPEP | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs776965284, COSV55592045; called by muse, mutect2, varscan2
- ARAP3 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1172784299, COSV53351081; called by muse, mutect2, varscan2
- ARL13B | c.734G>A p.G245D (on ENST00000394222 / NM_001174150.2; = p.G138D on NM_144996.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV57398697; called by muse, mutect2, varscan2
- BAHCC1 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs572608781, COSV57027517; called by muse, mutect2, varscan2
- BARHL2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776330330, COSV64981391; called by muse, mutect2, varscan2
- BCLAF1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as rs140335385; called by muse, mutect2, varscan2
- BIRC6 | c.7681G>A p.V2561I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs144411884; called by muse, mutect2, varscan2
- BTBD11 | c.2492G>A p.R831Q (on ENST00000280758 / NM_001018072.2; = p.R368Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs374710412, COSV99776971; called by muse, mutect2, varscan2
- CA14 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64873818; called by muse, mutect2, varscan2
- CACNA1C | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59726560; called by muse, mutect2, varscan2
- CACNA2D1 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100666912; called by muse, mutect2, varscan2
- CCNL1 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55819496; called by muse, mutect2, varscan2
- CDH2 | c.153A>C p.E51D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV52271452, COSV99296595; called by muse, mutect2, varscan2
- CELSR1 | c.3377G>A p.C1126Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs774178984, COSV53084720; called by muse, mutect2, varscan2
- CENPN | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763647933, COSV59904316; called by mutect2, varscan2
- CFH | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as rs145347741, CM100538; called by muse, mutect2, varscan2
- CRTAC1 | c.139T>C p.Y47H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV54002813; called by muse, mutect2, varscan2
- CRYBG3 | c.8073G>C p.L2691F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.308); catalogued as COSV99477184; called by muse, mutect2
- CSMD1 | c.6435C>T p.A2145= (on ENST00000520002; = p.A2144= on NM_033225.6) | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs1411319793, COSV59333202; called by muse, mutect2, varscan2
- CSMD2 | c.3882C>A p.H1294Q | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV53918924; called by muse, mutect2
- DCAF4L1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs1480842979, COSV60786280, COSV60786538; called by muse, mutect2, varscan2
- DDB1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1359685429, COSV57103278; called by muse, mutect2, varscan2
- DENND2A | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV52052401; called by muse, mutect2, varscan2
- DIP2C | c.1946G>A p.C649Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV55160912; called by muse, mutect2
- DMD | c.7075C>A p.Q2359K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.138); catalogued as CM098441, COSV58916236; called by muse, varscan2
- DNM1 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57852184; called by muse, mutect2, varscan2
- EIF2AK3 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV57548425; called by muse, mutect2, varscan2
- EIF3I | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1289414671, COSV59084575; called by muse, mutect2, varscan2
- EXT1 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV65480383; called by muse, mutect2, varscan2
- FADS6 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.08); catalogued as rs755346481, COSV59602717; called by muse, varscan2
- FCER1A | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs557521303, COSV63667400; called by muse, mutect2
- FLG | c.11096G>A p.R3699Q | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.097); catalogued as rs754536597, COSV100911786; called by muse, mutect2, varscan2
- GABRG3 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.14); catalogued as COSV61520180; called by muse, mutect2, varscan2
- GAS7 | c.1409G>T p.R470L (on ENST00000432992 / NM_201433.2; = p.R330L on NM_003644.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60436588, COSV60437469; called by muse, mutect2, varscan2
- GPC5 | c.1257G>T p.W419C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65602956, COSV65609849; called by muse, mutect2
- GRM1 | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51162442; called by muse, mutect2
- GRM7 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63146510; called by muse, varscan2
- GYPB | c.199A>C p.I67L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV51628236; called by muse, mutect2, varscan2
- HCN1 | c.1892A>C p.E631A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV57514997; called by muse, mutect2, varscan2
- HCN1 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57515004; called by muse, mutect2
- HDAC11 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769352859, COSV55473535; called by muse, mutect2, varscan2
- HDLBP | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs1019420712, COSV100191807, COSV60496726; called by muse, mutect2
- IFI44L | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV60727929; called by muse, mutect2, varscan2
- IL1RAPL2 | c.362C>A p.S121* | Nonsense Mutation (SNP) | VAF 10/201 reads (5%) | catalogued as COSV61161288; called by muse, mutect2
- IMPG1 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV64058640; called by muse, mutect2
- INTS8 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58250858; called by muse, mutect2, varscan2
- ITIH5 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV56905937; called by muse, mutect2, varscan2
- ITIH6 | c.1130A>C p.N377T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV54489822; called by muse, mutect2
- KCNU1 | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1388573146, COSV67756636; called by muse, mutect2, varscan2
- KDELR2 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); catalogued as COSV99330666; called by muse, mutect2
- KLKB1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs753850802, COSV52996284; called by muse, mutect2
- KRT3 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs780811924, COSV58815841; called by muse, mutect2, varscan2
- KRT35 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs573378713, COSV55843204; called by muse, mutect2, varscan2
- KRT39 | c.1400A>G p.E467G | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749011755, COSV62916858; called by muse, mutect2, varscan2
- LAMA1 | c.1817C>T p.S606L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs372377426; called by muse, mutect2, varscan2
- LENG9 | c.567G>C p.K189N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV56618548; called by muse, mutect2, varscan2
- LRCH1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV60848239; called by muse, mutect2, varscan2
- LRP12 | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52626891; called by muse, mutect2, varscan2
- LRP1B | c.13750G>T p.E4584* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV67226739; called by muse, mutect2, varscan2
- LRP1B | c.9636A>C p.Q3212H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV67229185; called by muse, mutect2, varscan2
- LRP1B | c.2577A>C p.Q859H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63341545, COSV63341769; called by muse, mutect2, varscan2
- LRP2 | c.6796G>T p.E2266* | Nonsense Mutation (SNP) | VAF 16/137 reads (12%) | catalogued as COSV55556759, COSV55573687; called by muse, mutect2, varscan2
- LRRC7 | c.1703G>C p.C568S (on ENST00000651989 / NM_001370785.2; = p.C535S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV50472337; called by muse, mutect2, varscan2
- LRRK2 | c.5057A>T p.E1686V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV54155640; called by muse, mutect2
- MAGEB18 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV57464221, COSV57465130; called by muse, varscan2
- MAGEB2 | c.512T>G p.V171G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV66780894; called by muse, mutect2, varscan2
- MAGEB6 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs142927857, COSV66872232; called by muse, mutect2, varscan2
- MAN2B1 | c.2362A>T p.N788Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV55472509; called by muse, mutect2, varscan2
- MFAP1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1231367167, COSV51039295; called by muse, mutect2, varscan2
- MICU2 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66674202; called by muse, mutect2, varscan2
- MROH9 | c.1386A>C p.Q462H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.951); catalogued as COSV63011811; called by muse, mutect2, varscan2
- MS4A14 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV55735349; called by muse, mutect2, varscan2
- NIPA2 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61682712; called by muse, mutect2, varscan2
- NLGN4X | c.1807A>G p.I603V | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV52021706; called by muse, mutect2, varscan2
- NLRP11 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1568629768, COSV100789730, COSV64085509; called by muse, mutect2, varscan2
- NR4A1 | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54483112; called by muse, mutect2, varscan2
- NRXN1 | c.1470C>A p.F490L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100456647, COSV58458612; called by muse, mutect2, varscan2
- NSD1 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100729582; called by muse, mutect2
- NUP153 | c.2933A>G p.N978S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1009020190, COSV50450609; called by muse, mutect2, varscan2
- OR10G2 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.111); catalogued as COSV73390387; called by muse, mutect2
- OR2T12 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV58777798; called by muse, mutect2, varscan2
- OR4C16 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1404669415, COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2, varscan2
- OR4P4 | c.395T>G p.I132S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV58922180, COSV58923234; called by muse, mutect2, varscan2
- OR6K3 | c.823T>G p.L275V (on ENST00000368146; = p.L259V on NM_001005327.2) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- OR8D4 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs755248753, COSV58429975, COSV58430359; called by muse, mutect2
- OSBPL3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750989138, COSV100513854, COSV57657405; called by muse, mutect2, varscan2
- P2RY6 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs780427456, COSV62936821; called by muse, mutect2
- PCDH15 | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs778369017, COSV57323872; ClinVar: uncertain significance; called by mutect2, varscan2
- PCDH17 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV64971354; called by muse, mutect2, varscan2
- PCDH17 | c.3179A>C p.K1060T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV64974882; called by muse, mutect2, varscan2
- PCDHA13 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781850899, COSV56508829; called by muse, mutect2, varscan2
- PCDHB4 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV52023261; called by muse, mutect2
- PCDHGB3 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs548499010, COSV53919749; called by muse, mutect2, varscan2
- PCDHGB4 | c.1386C>A p.N462K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53962197; called by muse, mutect2, varscan2
- PCLO | c.13221A>C p.E4407D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV61639554; called by muse, mutect2, varscan2
- PCNX3 | c.1994T>G p.F665C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63137270; called by muse, mutect2, varscan2
- PDE3A | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV62974473; called by muse, mutect2
- PEG3 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55631114, COSV55635999; called by muse, mutect2, varscan2
- PGR | c.2051T>A p.I684N | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV54802500; called by muse, mutect2, varscan2
- PIGG | c.1585G>A p.V529M (on ENST00000453061 / NM_001127178.3; = p.V521M on NM_017733.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs373234665; called by muse, mutect2, varscan2
- PKDREJ | c.5882C>G p.A1961G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV53549797; called by muse, mutect2, varscan2
- PLAT | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774851580, COSV54276067; called by muse, mutect2, varscan2
- PRKN | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); catalogued as COSV100632105, COSV58231609; called by muse, mutect2
- PXDN | c.4017G>T p.E1339D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53236354; called by muse, mutect2, varscan2
- PYROXD1 | c.364T>C p.C122R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as rs531545980, COSV53710044; called by muse, mutect2, varscan2
- RAD23A | c.600G>A p.T200= | Splice Region (SNP) | VAF 43/127 reads (34%) | catalogued as COSV57127189; called by muse, mutect2, varscan2
- RANBP6 | c.839G>C p.S280T | Missense Mutation (SNP) | VAF 635/692 reads (92%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs762313027, COSV52389751; called by muse, mutect2, varscan2
- RASGRP3 | c.823A>C p.T275P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101274813; called by muse, mutect2, varscan2
- RASGRP3 | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101274815; called by muse, mutect2, varscan2
- RBFOX1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs755458164, COSV60948155; called by muse, mutect2, varscan2
- RIMS2 | c.2846G>T p.R949I (on ENST00000666250 / NM_001348490.2; = p.R757I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV51687844; called by muse, mutect2, varscan2
- RIPK4 | c.2080G>A p.E694K (on ENST00000352483; = p.E646K on NM_020639.3) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.953); catalogued as COSV60187789; called by muse, mutect2, varscan2
- ROBO2 | c.3800G>T p.S1267I | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59908229; called by muse, mutect2
- ROBO2 | c.4043T>C p.V1348A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100168128, COSV59947404; called by muse, mutect2, varscan2
- RUSC1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV99430051; called by muse, mutect2
- RXFP2 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as rs369297578; called by muse, mutect2, varscan2
- SAMD9L | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV59082155; called by muse, mutect2, varscan2
- SEMG1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs199672858, COSV54871705, COSV54872099; called by muse, mutect2, varscan2
- SETD2 | c.6394C>T p.R2132W | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs769623377, COSV57434067, COSV57439432; called by muse, mutect2, varscan2
- SEZ6L | c.1683G>A p.A561= | Splice Region (SNP) | VAF 77/282 reads (27%) | catalogued as rs199961565, COSV50662660, COSV50676296; called by muse, mutect2, varscan2
- SI | c.606A>C p.Q202H | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV52267958; called by muse, mutect2
- SLC35G3 | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52011440; called by muse, mutect2, varscan2
- SLC44A4 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs781022323, COSV57667476; called by muse, mutect2
- SLCO1B3 | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53935064, COSV99680771; called by muse, mutect2, varscan2
- SLCO3A1 | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV59231029; called by muse, mutect2, varscan2
- SNRPN | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1294150531, COSV57597251; called by muse, mutect2, varscan2
- STAB1 | c.6798C>A p.H2266Q | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV58737378; called by muse, mutect2, varscan2
- SYT16 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs376295336, COSV70857123; called by muse, mutect2
- TACR3 | c.1214G>T p.R405I | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV59198676, COSV59202465; called by muse, mutect2, varscan2
- TAS2R13 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV66831702, COSV66831859; called by muse, mutect2, varscan2
- TECTA | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV50717891, COSV99880636; called by muse, mutect2, varscan2
- TEF | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241364727, COSV56747199; called by muse, mutect2, varscan2
- TET1 | c.5555C>T p.P1852L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as rs576727317, COSV65385343; called by muse, mutect2, varscan2
- TG | c.7281G>T p.E2427D | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55079283; called by muse, mutect2
- TH | c.1450C>T p.R484C (on ENST00000381178 / NM_199292.3; = p.R453C on NM_000360.4) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755922032, COSV51747352; called by muse, mutect2, varscan2
- TNFRSF19 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750280848, COSV50314525; called by muse, mutect2, varscan2
- TNRC6C | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs781193694, COSV56942630; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 51/187 reads (27%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TRDN | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62123295; called by muse, mutect2, varscan2
- TTBK2 | c.1724C>G p.T575S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV51163079; called by muse, mutect2, varscan2
- TTC23L | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs934198849, COSV72205918, COSV72205958; called by muse, mutect2
- TUBA1A | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV99853766; called by muse, mutect2, varscan2
- UBE3D | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147405452; called by muse, mutect2
- UBQLN3 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61164436; called by muse, mutect2, varscan2
- UNC5C | c.224A>T p.K75M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71660233; called by muse, mutect2, varscan2
- USP44 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV51564545; called by muse, mutect2, varscan2
- VPS16 | c.2497A>G p.R833G | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV66795622; called by muse, mutect2, varscan2
- ZCCHC8 | c.345T>A p.F115L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV60318539; called by muse, mutect2, varscan2
- ZFHX4 | c.8175G>T p.Q2725H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV50837318, COSV50934738; called by muse, mutect2, varscan2
- ZNF236 | c.2549G>T p.G850V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV53489783; called by muse, mutect2, varscan2
- ZNF347 | c.737T>C p.L246S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61969108; called by muse, mutect2, varscan2
- ZNF454 | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1021026896, COSV60768703; called by muse, mutect2, varscan2
- ZNF516 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392734495, COSV101487311, COSV71587115; called by muse, mutect2
- ZNF99 | c.2004A>C p.K668N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV68055472; called by muse, mutect2, varscan2
- AL031777.2 | c.116dup p.N39Kfs*62 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- APC | c.4393_4394dup p.S1465Rfs*9 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, varscan2
- IFT88 | c.1805_1807del p.G602del (on ENST00000319980 / NM_001318493.2; = p.G593del on NM_006531.5 and 9 other RefSeq transcripts) | In Frame Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- IGF2R | c.1505del p.V502Gfs*55 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, varscan2
- IGLC2 | c.282C>A p.S94R | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- POLR2A | c.5315C>T p.T1772I | Missense Mutation (SNP) | VAF 59/376 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RAB5B | c.399del p.N133Kfs*36 | Frame Shift Del (DEL) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- TRPV2 | c.966C>G p.S322R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCC10 | c.3855C>G p.G1285= (on ENST00000372530 / NM_001198934.2; = p.G1257= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV55088802; called by muse, mutect2, varscan2
- ACTN4 | c.1885C>T p.L629= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV53146654; called by muse, mutect2, varscan2
- ADAMTS19 | c.2136C>A p.S712= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV50753404; called by muse, mutect2, varscan2
- ANO3 | c.1398G>A p.L466= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV55553590, COSV55554911; called by muse, mutect2, varscan2
- ARHGAP11B | c.396T>C p.I132= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101451818; called by mutect2, varscan2
- CCDC172 | c.39C>T p.T13= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1261359308, COSV60938128; called by muse, mutect2, varscan2
- CCDC85A | c.1278A>G p.R426= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs369400795; called by muse, mutect2
- CERS3 | c.1095A>G p.L365= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs754927877, COSV52569462; called by mutect2, varscan2
- CHST7 | c.453C>T p.G151= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV52100142; called by muse, mutect2, varscan2
- COPB2 | c.2253G>T p.L751= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV60350329; called by muse, mutect2, varscan2
- CXCR5 | c.747G>A p.Q249= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52685103; called by muse, mutect2, varscan2
- DCAF8L1 | c.807A>G p.E269= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV71595290, COSV71595338; called by muse, mutect2, varscan2
- DGKD | c.306C>T p.S102= (on ENST00000264057 / NM_152879.3; = p.S58= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs761499504, COSV51052340; called by muse, mutect2, varscan2
- DNM3 | c.63G>A p.S21= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs958126966, COSV62459430; called by muse, mutect2
- DPYS | c.1171A>C p.R391= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV59826759, COSV59826868, COSV59826998; called by muse, mutect2, varscan2
- EBP | c.513C>T p.R171= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs147786080, COSV52141793; called by muse, mutect2, varscan2
- FLG | c.10065G>T p.V3355= | Silent (SNP) | VAF 74/527 reads (14%) | catalogued as COSV64242732; called by muse, mutect2, varscan2
- FOXO3 | c.1206G>A p.S402= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs939659504, COSV59628601; called by muse, mutect2, varscan2
- FUT4 | c.1401C>A p.S467= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV62469457; called by muse, mutect2
- GATA4 | c.1032C>T p.S344= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs755482369, COSV58732917; ClinVar: likely benign; called by muse, mutect2, varscan2
- GUCY1A2 | c.639T>C p.S213= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV56488828, COSV99977885; called by muse, mutect2, varscan2
- IL10RA | c.750C>T p.L250= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs267602711, COSV57140911; called by muse, mutect2, varscan2
- KCNC2 | c.507C>T p.F169= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs960429937, COSV54365041, COSV54370311; called by muse, mutect2
- MAGEB16 | c.294C>T p.S98= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV67874022; called by muse, mutect2, varscan2
- MAP3K15 | c.1695A>G p.E565= | Silent (SNP) | VAF 57/271 reads (21%) | catalogued as COSV58831324; called by muse, mutect2, varscan2
- MAP3K8 | c.1281G>A p.S427= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs150841663; called by mutect2, varscan2
- MRPS30 | c.39T>G p.G13= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs963177485, COSV72361406; called by muse, mutect2
- MSGN1 | c.252C>T p.V84= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1361051569, COSV55262834; called by muse, mutect2
- MYO1D | c.2268C>T p.Y756= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as rs150683059; called by muse, mutect2
- OGT | c.564G>A p.P188= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as rs764536052, COSV65480985; called by muse, mutect2, varscan2
- OR10H2 | c.423C>T p.C141= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs147373947; called by muse, mutect2, varscan2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- OR6C6 | c.363C>T p.Y121= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1565656357, COSV64455835; called by muse, mutect2, varscan2
- PCDHA9 | c.1353C>T p.N451= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs1554143388, COSV65324575; called by muse, mutect2, varscan2
- PCDHGB2 | c.1605C>T p.R535= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV53902725, COSV53962165; called by muse, mutect2, varscan2
- PDE4B | c.867A>C p.P289= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV58479705; called by muse, mutect2, varscan2
- PLCB1 | c.918C>T p.V306= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV62054522; called by muse, mutect2, varscan2
- PLPP1 | c.288C>T p.A96= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99301864; called by muse, mutect2, varscan2
- PMM2 | c.645C>T p.G215= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs765599626, COSV51632141; called by muse, mutect2, varscan2
- PRDM13 | c.480C>T p.C160= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV65029905; called by muse, mutect2, varscan2
- PRICKLE3 | c.1632T>G p.S544= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV66234850; called by muse, mutect2
- RAB6D | c.603C>T p.V201= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- RTN2 | c.318C>A p.G106= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV55594455; called by muse, mutect2, varscan2
- SCUBE3 | c.1486C>T p.L496= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs530234601, COSV51457451; called by muse, mutect2, varscan2
- STAT3 | c.1449G>A p.L483= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV52888365; called by muse, mutect2, varscan2
- TDRD6 | c.4321C>A p.R1441= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV60176257; called by muse, mutect2, varscan2
- TFAP2C | c.153C>T p.V51= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs767119816, COSV52371676; called by muse, mutect2, varscan2
- TMEM132B | c.3108C>T p.D1036= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs372923015; called by muse, mutect2, varscan2
- TSHZ3 | c.2022G>A p.P674= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs151270303; called by muse, mutect2, varscan2
- UBQLNL | c.192A>G p.Q64= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1321352008, COSV66493634; called by muse, mutect2
- ZC3H13 | c.4167C>T p.R1389= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV54455533; called by muse, mutect2, varscan2
- ZNF134 | c.705C>T p.S235= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs376842871; called by muse, mutect2, varscan2
- ZNF253 | c.990T>C p.H330= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV63037380; called by muse, mutect2, varscan2
- ZNF431 | c.759T>A p.I253= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV60673448, COSV60674319; called by muse, mutect2
- ZNF583 | c.1053T>C p.P351= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV52402861; called by muse, mutect2, varscan2
- ZNF804A | c.2424T>G p.P808= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV56451775; called by muse, mutect2, varscan2
- IQCJ | c.291+16C>A | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as COSV101188628; called by muse, mutect2, varscan2
- OR2W5 | n.645C>T | RNA (SNP) | VAF 10/80 reads (13%) | catalogued as rs753312079; called by muse, varscan2
- RIMS2 | c.1692+311C>A | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99176486; called by muse, mutect2
- VPS26C | chr21:37221473 A>C | 3'Flank (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
